CCDI case PBBRRE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7386f6cb-1a13-43e6-8f46-c8487f0f49b4

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.6 years (946 days).

Biospecimens (3 samples)
- Sample 0DF2DK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DF2DL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DF2DM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
